Somatic mutation profile of tumor specimen TCGA-FP-8210-01A (aliquot TCGA-FP-8210-01A-11D-2340-08) from TCGA case TCGA-FP-8210, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 48.1 years (17,562 days).
Specimen TCGA-FP-8210-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21f38125-46de-4891-89a6-94635538901e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-8210-11A (Solid Tissue Normal), aliquot TCGA-FP-8210-11A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/963df530-df5f-46dc-b5fa-628e890c3bbb

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN2 | c.1278G>A p.M426I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54338280; called by muse, mutect2
- CDH1 | c.770A>G p.D257G | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1555515446, COSV55737637, COSV55737694; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLU7 | c.1663A>T p.M555L | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV51789254; called by muse, mutect2
